Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7430, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7430-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

- (A) "RIGHT OMOHYOID":
Skeletal muscle with suture granulomata; no tumor present.
- (B) "RIGHT PAROTID ARTERY":
Connective tissue and nerve; no tumor present.
- (C) "CERVICAL ESOPHAGUS":
Connective tissue with reactive changes; no tumor present.
- (D) "RIGHT LATERAL NECK DISSECTION":
Ten lymph nodes, no tumor present.
- (E) "SYMPATHETIC NERVE SHEATH":
GRADE II SQUAMOUS CARCINOMA INVOLVING NERVE (PERINEURAL INVASION).
- (F) "TOTAL LARYNGECTOMY, TOTAL THYROIDECTOMY, LEFT ANTERIOR COMPARTMENT DISSECTION":
GRADE II SQUAMOUS CARCINOMA INVOLVING ANTERIOR CONNECTIVE TISSUES, DEEP SUBCUTANEOUS TISSUE, ESOPHAGUS, LYMPHO-VASCULAR INVASION IS PRESENT; TUMOR IS PRESENT AT THE PROXIMAL AND DISTAL SOFT TISSUE RESECTION MARGINS.
One anterior compartment lymph node, no tumor present.
Thyroid gland, no tumor present.
- (G) "TRANSDUCED TUMOR":
FRAGMENTS OF GRADE II SQUAMOUS CARCINOMA.
- (H) NON-TRANSDUCED TUMOR":
FRAGMENTS OF GRADE II SQUAMOUS CARCINOMA WITH INFILTRATION OF CONNECTIVE TISSUE, LYMPHO-VASCULAR INVASION IS PRESENT.
- (I) "VAGUS NERVE":
GRADE II SQUAMOUS CARCINOMA IN CONNECTIVE TISSUE; NO DEFINITE VAGUS NERVE IS IDENTIFIED.
- (J) "RIGHT SYMPATHETIC CHAIN":
GRADE II SQUAMOUS CARCINOMA INVOLVING NERVE AND CONNECTIVE TISSUE.
- (K) "TUMOR BASE OF SKULL":
GRADE II SQUAMOUS CARCINOMA EXTENSIVELY INVOLVING CONNECTIVE TISSUE AND PERINEURAL COMPARTMENTS; TUMOR IS PRESENT AT THE DESIGNATED, INKED RESECTION MARGIN.

SPECIMEN

- (A) "RIGHT OMOHYOID":
- (B) "RIGHT PAROTID ARTERY":
- (C) "CERVICAL ESOPHAGUS":
- (D) "RIGHT LATERAL NECK DISSECTION":
- (E) "SYMPATHETIC NERVE SHEATH":
- (F) "TOTAL LARYNGECTOMY, TOTAL THYROIDECTOMY, LEFT ANTERIOR COMPARTMENT
- (G) "TRANSDUCED TUMOR":
- (H) NON-TRANSDUCED TUMOR":
- (I) "VAGUS NERVE":
- (J) "RIGHT SYMPATHETIC CHAIN":
- (K) "TUMOR BASE OF SKULL":

[page 2 of 2]
SNOMED CODES

T-56000,M-80706,T1A000,M-80706

Source: NCI Genomic Data Commons file 0894616c-5c51-4fc6-a4c7-ef1948e623e0 (TCGA-CV-7430.E067C178-DCAC-47F2-993F-C64AC96328FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).